Somatic mutation profile of tumor specimen MP2PRT-PAUVZN-TBP1-A (aliquot MP2PRT-PAUVZN-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUVZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,414 days).
Specimen MP2PRT-PAUVZN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5610917-a801-44c2-9a66-dc0dd70aa84d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUVZN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUVZN-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7a5792f-8f96-408e-b5ee-fc9925e9f1c2

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADM1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 86/361 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1020817643; called by muse, mutect2, varscan2
- FAM47B | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 67/1044 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1270166173, COSV61452566; called by muse, mutect2
- FOXC2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 161/584 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as CD021827; called by muse, mutect2, varscan2
- GABRP | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs781550114, COSV54662402; called by muse, mutect2, varscan2
- GPR31 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 122/523 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1335437298, COSV100834115, COSV64761123; called by muse, mutect2, varscan2
- NRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54736435; called by muse, mutect2, varscan2
- PDE1C | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs760282457, COSV58513096; called by muse, mutect2, varscan2
- RFX4 | c.1510G>A p.A504T (on ENST00000392842 / NM_213594.3; = p.A410T on NM_032491.6) | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs145361726; called by muse, mutect2
- SCN8A | c.3503G>A p.R1168Q | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs763817893; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANC2 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757851333, COSV67332369; called by muse, mutect2, varscan2
- FAT3 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PDE6C | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 24/680 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- PDK4 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TCIM | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 76/500 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLRT1 | c.1743C>T p.G581= | Silent (SNP) | VAF 44/496 reads (9%) | catalogued as rs200134025, COSV99734499; called by muse, mutect2
- GCNA | c.570C>T p.D190= | Silent (SNP) | VAF 188/1044 reads (18%) | catalogued as rs1437621461; called by muse, varscan2
- OTOG | c.240C>T p.V80= | Silent (SNP) | VAF 27/370 reads (7%) | catalogued as rs999578353; called by muse, mutect2
- SON | c.1554G>T p.G518= | Silent (SNP) | VAF 120/657 reads (18%) | catalogued as rs747899830; called by muse, mutect2, varscan2
- TMED2 | c.171C>T p.I57= | Silent (SNP) | VAF 22/271 reads (8%) | called by muse, mutect2
